Surgical pathology report (de-identified scan), TCGA case TCGA-J9-A8CL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Melbourne Health, specimen TCGA-J9-A8CL-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Adenocarcinoma, acinar 8/40/3
Site Prostate NOS C61.9
J 11/27/13

DOB:

Sex:

Episode Results

1. ☐ - HIST
2. ☐ - VOLUMETRIC
3. ☐ - SYNOPSIS

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

HISTOPATHOLOGY REPORT

CLINICAL NOTES :

Right sided Gleason 9, T3. PSA 12. Nn right neurovascular bundle dissected ex-vivo (in research facility, bare area inked green). Also separate left neurovascular bundle tissue at apex.

MACROSCOPIC :

Specimen 1: Labelled prostate. A prostate and attached seminal vesicles 52 x 40 x 37 mm and weighing 40 g

Block designation:

Right apex: A and B. Left apex: C and D

Right base: E and F. Left base: H to K

Apex to base, right: L to Q. Apex to base, left: R to W. P23

Tissue banking - Benign: left TZ, Tumour: right PZ (correctly identified).

Specimen 2: Labelled left neurovascular bundle, excised postop. Tan tissue 16 x 13 x 5 mm. Trisected. A1.

MICROSCOPIC :

Specimen 1: The sections show extensive bilateral prostate adenocarcinoma. The index tumour is

[page 2 of 4]
based in the right lobe from apex to base, with extension across the midline into the left lobe, and is Gleason score 4+5=9. There are additional tumour foci in the left peripheral zone and transition zone, Gleason score 3+4(10%)=7 and 3+3=6 respectively. There is multifocal perineural invasion and lymphovascular invasion, including extraprostatic foci.

There is multifocal extraprostatic extension involving;

right posterolateral angle, 30mm, clear of margins;

right apex, several foci, up to 10mm, with positive pathological margin (1mm, Gleason patterns 4 and 5); and

right and left base, multiple foci including direct invasion of both seminal vesicles, up to 25mm, with positive pathological margins (8 and 4mm, Gleason patterns 4 and 5).

Specimen 2: The sections show benign prostatic tissue and adjacent fibrofatty stroma. There is no evidence of invasive malignancy.

CONCLUSION:

Specimen 1 and 2: Robot assisted laparoscopic radical prostatectomy and left neurovascular bundle tissue -- Bilateral prostate adenocarcinoma, index tumour right peripheral zone, Gleason score 4+5=9. Multifocal extraprostatic extension including right posterolateral (clear margins), right apex (with positive pathological margin), right and left base/seminal vesicles (with positive pathological margins).

Pathological stage - pT3b.

Reported by

All Rights Reserved.

Email:

[page 3 of 4]
Episode Results:

Patient Details

DOB:

Sex:

Episode Results

1. - HIST
2. - VOLUMETRIC
3. - SYNOPSIS

Doctor Details

Requesting Doctor:

Copy-To Doctors:

Episode Details

Status:

Results Available

Collection Date:

Reported Date:

Episode:

SYNOPTIC REPORT: CARCINOMA OF PROSTATE

Specimen type : Robot assisted laparoscopic radical prostatectomy and left neurovascular bundle.

Tumour type:

Index tumour (right PZ): Adenocarcinoma, acinar type

Other tumour foci (left PZ and TZ): Adenocarcinoma, acinar type

Gleason score:

Index tumour: 4+5=9

Other tumour foci: 3+4(10%)=7 and 3+3=6

Site: See volumetric analysis.

Unifocal/Multifocal : Multifocal

Perineural invasion : Present, multifocal

Lymphovascular invasion : Present, multifocal, including extraprostatic foci.

Extraprostatic extension : Present, multifocal, right posterolateral angle (30mm, right apex (up to 10mm) and right and left base (up to 25mm)).

[page 4 of 4]
Seminal vesicle involvement : Present, bilateral

Pathological margin status : Positive, right apex (1mm, Gleason patterns 4 and 5, in EPE), right and left base/SV (8 and 4mm, Gleason patterns 4 and 5 in EPE).

Presence of PIN : Present, high-grade PIN

Lymph nodes: Not sampled.

Tumour Volume:

Peripheral Zone (black): 19.0cc

Transition Zone (green): 0.6cc

Pathologic stage: pT3b

Reported by

All Rights Reserved.
Phone:

Email:

IMF/PA Discrepancy		✓

Source: NCI Genomic Data Commons file 9f414a46-ce58-46f2-8278-c62b8003cad4 (TCGA-J9-A8CL.062E0E86-B3E0-4CC0-9BE5-0EBDB81DCB5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).